Gene-level copy-number profile of tumor specimen TCGA-AG-A016-01A from TCGA case TCGA-AG-A016, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.2 years (20,178 days).
Specimen TCGA-AG-A016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.24a2b91f-bb67-4953-a834-175409a4a378.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A016-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f0e1d39-4a03-4385-b48c-1c0c57e47ccb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,226; copy number 2: 40,204; copy number 3: 13,161; copy number 4: 2,653; copy number 5: 1,000; copy number 6: 18; copy number 7: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A016-01A-01D-A003-01): tumor purity 0.87, ploidy 2.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,027 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,871,895–29,945,884, 11 genes, copy number 6: HCP5B, AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1.
- chr6:31,394,289–31,494,935, 8 genes, copy number 7: AL645933.2, MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5, MICB-DT.
- chr6:31,496,689–31,496,790, 1 gene, copy number 7: Y_RNA.
- chr7:148,697,914–148,890,513, 5 genes, copy number 5 (within-gene range 3–5): CUL1, EZH2, RNU7-20P, Metazoa_SRP, RN7SL569P.
- chr8:71,155,454–71,204,223, 1 gene, copy number 5: AC022858.1.
- chr8:83,200,952–83,408,900, 3 genes, copy number 5: AC090132.1, AC090132.2, LINC01419.
- chr8:117,794,490–121,119,754, 39 genes, copy number 5: EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1.
- chr12:19,413,153–19,419,161, 2 genes, copy number 5: PDCD5P1, AC091805.2.
- chr13:70,923,664–73,661,891, 30 genes, copy number 5: MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr13:73,800,074–73,802,203, 1 gene, copy number 5: AL138713.1.
- chr13:105,690,429–106,961,392, 21 genes, copy number 5: AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1.
- chr16:78,166,717–78,168,514, 1 gene, copy number 5: AC009044.1.
- chr17:46,029,916–46,225,389, 1 gene, copy number 6 (within-gene range 3–6): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 6: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr20:30,278,906–64,313,132, 898 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 838. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
